Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7254, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7254-01A (Primary Tumor).

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) BIOPSY, RIGHT TRUE VOCAL CORD:
INVASIVE SQUAMOUS CARCINOMA, GRADE III.
- (B) RIGHT CORDECTOMY:
INVASIVE SQUAMOUS CARCINOMA, GRADE III. PRESENCE OF LYMPHATIC
INVASION. TUMOR AT DEEP MARGIN OF RESECTION AND LEFT ANTERIOR
COMMISSURE.
- (C) TISSUE OVERLYING ARYTENOID CARTILAGE:
SQUAMOUS CARCINOMA IN FIBROVASCULAR TISSUE.
- (D) FALSE CORD MARGIN:
Squamous mucosa, no tumor.
- (E) POSTERIOR COMMISSURE MARGIN:
Mucosa and muscle, no tumor.
- (F) LEFT ANTERIOR COMMISSURE:
SQUAMOUS CARCINOMA INVASIVE.
- (G) POSTERIOR SUBGLOTTIC:
Fibrous tissue, no tumor.
- (H) ANTERIOR SUBGLOTTIC:
Fibroconnective tissue, no tumor.
- (I) NEW ARYTENID MARGIN (NEW C):
Squamous mucosa and muscle, no tumor.
- (J) NEW ANTERIOR COMMISSURE MARGIN (NEW F):
Dysplastic epithelium, no carcinoma present.
- (K) THYROID CARTILAGE (NEW BASE):
cartilage, no carcinoma present.

SPECIMEN

- (A) BIOPSY, RIGHT TRUE VOCAL CORD:
- (B) RIGHT CORDECTOMY:
- (C) TISSUE OVERLYING ARYTENOID CARTILAGE:
- (D) FALSE CORD MARGIN:
- (E) POSTERIOR COMMISSURE MARGIN:
- (F) LEFT ANTERIOR COMMISSURE:
- (G) POSTERIOR SUBGLOTTIC:
- (H) ANTERIOR SUBGLOTTIC:
- (I) NEW ARYTENID MARGIN (NEW C):
- (J) NEW ANTERIOR COMMISSURE MARGIN (NEW F):
- (K) THYROID CARTILAGE (NEW BASE):

SNOMED CODES

T-24400,M-80703

Source: NCI Genomic Data Commons file 8a720d21-358e-40f4-9806-59dd7d41244b (TCGA-CV-7254.C094C14C-2781-439D-BA5E-310996F8DC0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).